Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8012, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8012-01A (Primary Tumor).

Microscopic

Microscopic examination reveals a moderately hypercellular glial neoplasm. The tumor consists of infiltrating glial cells with round to oval nuclei and prominent perinuclear halos. Cytologic atypia appears moderate. In areas, the neoplasm demonstrates focal microcystic change. There is focal hypercellularity. Neither microvascular proliferation nor necrosis are identified. An occasional microcalcification is identified. Only a rare mitotic figure is seen at up to one mitoses per ten high power fields. The findings appear consistent with an oligodendroglioma.

Addendum

The calculated MIB-1 labeling index is 2.7% consistent with a low grade glioma

Diagnosis

Oligodendroglioma Grade II

Source: NCI Genomic Data Commons file b8af6785-928c-45c7-8d44-ca7d3e1c7d92 (TCGA-HT-8012.D968744B-5830-4320-9143-58E4C4CB90A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).